Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A25C, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A25C-01A (Primary Tumor).

[page 1 of 3]
Specimen:

Received:

Status:

Req#:

Spec Type: SURGICAL P

Subm Dr:

PRELIMINARY DIAGNOSIS

LEFT BREAST CANCER INVASIVE

OPERATION PERFORMED

100-0-3

Carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS C50.9

4/27/11

DATE:

DOCTOR(S):

PROCEDURE: SENTINEL NODE BX/SIMPLE MASTECTOMY

TISSUE RECEIVED

- A. LT BREAST SIMPLE MASTECTOMY
- B. LT SENTINEL NODE #1
- C. LT SENTINEL NODE #2

GROSS DESCRIPTION

RECEIVED IN 3 PARTS.

PART A RECEIVED LABELED [REDACTED] SIMPLE LEFT BREAST MASTECTOMY STITCH AT 12 O'CLOCK, IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 17.5 X 16 X 2.8 CM. THE NIPPLE IS UNREMARKABLE WITHIN A 9 X 2.5-CM SKIN ELLIPSE. ADDITIONALLY WITHIN THE CONTAINER ARE 2 IRREGULAR FRAGMENTS OF FATTY TISSUE WITH NO PALPABLE MASSES TOGETHER MEASURING 4.5 X 3 X 0.5 CM. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK, THE DEEP WITH BLACK. SECTIONING REVEALS 2 DISCRETE GRAY FIBROUS NODULES; THE MOST LATERAL IS AT 3 O'CLOCK MEASURING 1.5 X 1.1 X 1.5 CM. ADJACENT TO THIS SEPARATED BY 1.5 CM IN THE 6:30 AREA IS A MASS WITH A COIL CLIP MEASURING 2.2 X 1.8 X 2.1 CM. THESE ARE BOTH 0.5 CM FROM THE DEEP MARGIN. CENTRALLY, THE BREAST HAS DENSE TAN FIBROUS TISSUE, BUT THE PERIMETER OF THE SPECIMEN AND THE TISSUE ADJACENT TO THE DEEP MARGIN IS YELLOW FATTY TISSUE. THE 3 O'CLOCK LESION IS 0.7 CM FROM THE SUPERFICIAL MARGIN. THE 6 O'CLOCK LESION EXTENDS TO WITHIN 0.6 CM OF THE SUPERFICIAL MARGIN. SECTIONS ARE SUBMITTED AS FOLLOWS: A1--NIPPLE; A2--TISSUE BETWEEN THE TWO LESIONS; A3--3 O'CLOCK LESION TO INCLUDE DEEP MARGIN; A4--3 O'CLOCK LESION TO INCLUDE SUPERFICIAL MARGIN; A5 AND 6--FULL CROSS-SECTION OF 6 O'CLOCK LESION TO INCLUDE THE DEEP AND SUPERFICIAL MARGIN, RESPECTIVELY; A7--6 O'CLOCK LESION; A8--UPPER OUTER QUADRANT; A9--UPPER INNER QUADRANT; A10--LOWER INNER QUADRANT; A11--LOWER OUTER QUADRANT. TISSUE FROM EACH LESION IS SUBMITTED PER PROTOCOL.

PART B RECEIVED LABELED [REDACTED] LEFT SENTINEL NODE #1 HOT AND BLUE, IS AN OVOID FRAGMENT OF YELLOW-RED SOFT TISSUE MEASURING 1.7 X 1.0 X 0.9 CM. SECTIONING REVEALS A GROSSLY UNREMARKABLE 1.3-CM LYMPH NODE WITH CENTRAL FAT REPLACEMENT AND BLUE COLORATION. THIS IS SUBMITTED LABELED B, BISECTED.

PART C RECEIVED LABELED [REDACTED] LEFT SENTINEL NODE #2 HOT

[page 2 of 3]
Patient: [REDACTED]

(Continued)

Specimen: [REDACTED]

Received: [REDACTED]

Status: [REDACTED]

Req# [REDACTED]

Spec Type: SURGICAL P

Subm Dr: [REDACTED]

GROSS DESCRIPTION

(Continued)

AND BLUE, IS A 1.5 X 0.6 X 0.4-CM OVOID PORTION OF RED-TAN TISSUE. SECTIONING REVEALS THIS TO BE A GROSSLY UNREMARKABLE LYMPH NODE WITH BLUE COLORATION SUBMITTED LABELED C, BISECTED.

PATH PROVIDED

PROCEDURES:

88307/3, IMMUNOPEROXIDAS/2, A BLK/11, BBX X6, CBX X6

FINAL REPORT

PART A (LEFT BREAST, SIMPLE MASTECTOMY:

1. MODERATELY DIFFERENTIATED INFILTRATING DUCT CARCINOMA, NUCLEAR GRADE II/III, MODERATE MITOTIC INDEX AND TUBULE FORMATION 2, WITH A TOTAL NOTTINGHAM SCORE OF 6. RARE FOCI OF DCIS OF THE CRIBRIFORM AND SOLID TYPES, NUCLEAR GRADE II WITH LOW MITOTIC INDEX, ARE SEEN AT THE PERIPHERY OF THE TUMOR.
2. A 1.5-CM TUMOR IS IDENTIFIED IN THE 3 O'CLOCK LOCATION AND A 2.2-CM LESION IS IDENTIFIED IN THE 6 O'CLOCK PORTION WHICH ARE SEPARATED BY AT LEAST 1.5 CM OF BENIGN BREAST TISSUE.
3. THE MARGINS OF EXCISION, NIPPLE SKIN AND RANDOM SECTIONS OF REMAINING QUADRANTS ARE FREE OF TUMOR.
4. LYMPHOVASCULAR INVASION IS IDENTIFIED.
5. BIOPSY CHANGES ARE PRESENT.

IDC 2/2/2

rare DCIS 82
crib
solid

multifocal
1.5cm apart
2.2cm & 1.5cm

+ LVI
Bx L

PART B LEFT AXILLA, SENTINEL LYMPH NODE BIOPSY #1: METASTATIC BREAST CARCINOMA IS MULTIFOCALLY IDENTIFIED ON H&E STEP SECTIONS AND CYTOKERATIN STAINS IN 1 LYMPH NODE EXAMINED, THE LARGEST FOCUS OF WHICH MEASURES 3 MM IN GREATEST MICROSCOPIC DIMENSION. NO EVIDENCE OF EXTRANODAL EXTENSION.

1/1 SN

PART C LEFT AXILLA, SENTINEL LYMPH NODE BIOPSY #2: MULTIFOCAL METASTATIC BREAST CARCINOMA IS IDENTIFIED ON H&E STEP SECTIONS AND CYTOKERATIN STAINS IN 1 LYMPH NODE EXAMINED, THE LARGEST FOCUS OF WHICH MEASURES 2 MM IN GREATEST MICROSCOPIC DIMENSION. EXTRANODAL EXTENSION IS NOT PRESENT.

1/1 SN

[page 3 of 3]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Spec Type: SURGICAL P

Subm Dr:

DIAGNOSTIC/THERAPEUTIC MARKERS

Her-2/neu: NEGATIVE

Score: 1+

Reference Range: Negative 0 - 1+

Equivocal 2+

Positive 3+

Electronically signed by:

M.D.

See full scanned report for details.

Test performed at:

1. SENT TO: [REDACTED]
2. REQUESTED BY: DR [REDACTED]
3. DATE SENT: [REDACTED]
4. METHOD OF TRANSPORTATION: COURIER
5. NO. OF BLOCKS: 1 BLOCK A3
7. MATERIAL(S) TO BE RETURNED: Y
14. SPECIMEN SENT (Y/N): Y

Signed _____

M.D.

(prelim.)

Electronically signed by: _____

M.D.

Source: NCI Genomic Data Commons file d20d651a-3d77-484c-a9b3-525124a33d2c (TCGA-A2-A25C.1D4CA1BA-B534-4CEA-ABA5-EF9B31694204.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).